Somatic mutation profile of tumor specimen TCGA-P5-A77W-01A (aliquot TCGA-P5-A77W-01A-11D-A32B-08) from TCGA case TCGA-P5-A77W, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 37.1 years (13,545 days).
Specimen TCGA-P5-A77W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c37c1636-aaf4-4b05-881e-446004c11d16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A77W-10A (Blood Derived Normal), aliquot TCGA-P5-A77W-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad859643-4c4c-4e57-91fc-c37eb9d4dac3

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Frame Shift Del 3, Silent 2, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CCDC191 | c.1827G>T p.K609N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99878266; called by muse, mutect2
- CCDC198 | c.550A>T p.S184C | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99371255; called by muse, mutect2
- CCDC198 | c.548A>C p.Q183P | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99371256; called by muse, mutect2
- CXorf38 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100010153, COSV100010386; called by muse, mutect2, varscan2
- GNAI3 | c.353_354insG p.M119Hfs*10 | Frame Shift Ins (INS) | VAF 6/63 reads (10%) | catalogued as COSV100879882; called by mutect2, pindel
- HEATR5B | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs1278975169, COSV99249318; called by muse, mutect2, varscan2
- HMCN1 | c.5471T>A p.V1824D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99629467; called by muse, varscan2
- HMCN1 | c.5472T>G p.V1824= | Splice Region (SNP) | VAF 26/88 reads (30%) | catalogued as COSV99629469; called by muse, varscan2
- HMCN1 | c.5473C>T p.P1825S | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV54909503; called by muse, varscan2
- IRAK3 | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99706192; called by muse, mutect2, varscan2
- LGI1 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101004414; called by muse, mutect2, varscan2
- LY75 | c.1028C>A p.P343Q | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV55111394, COSV99716463; called by muse, mutect2, varscan2
- MATN2 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV99646332; called by muse, mutect2, varscan2
- MEP1A | c.704T>C p.F235S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100042735; called by muse, mutect2, varscan2
- OR10G2 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101606954; called by muse, mutect2
- PHKA2 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs756022581, COSV101177066; called by muse, mutect2, varscan2
- PLVAP | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs376999423; called by muse, mutect2, varscan2
- POP1 | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100855853; called by muse, mutect2
- SLC43A1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99561004; called by muse, mutect2
- ARID1A | c.2257_2258del p.M753Afs*63 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by pindel, varscan2
- CBX5 | c.42del p.E15Rfs*12 | Frame Shift Del (DEL) | VAF 33/117 reads (28%) | called by mutect2, pindel, varscan2
- CIC | c.2278_2279del p.V760Hfs*2 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel, varscan2
- SLCO4C1 | c.486A>G p.V162= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100195004; called by muse, mutect2, varscan2
- TGS1 | c.927A>T p.T309= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99485405; called by muse, mutect2, varscan2
- OR3A4P | n.702A>C | RNA (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
